Gene-level copy-number profile of tumor specimen TCGA-63-A5MR-01A from TCGA case TCGA-63-A5MR, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.35c31578-1fc0-475c-81c7-0878cc111db2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/72d1fa6d-6e8b-4bea-bed3-a71ddefa1dda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,895; copy number 2: 31,439; copy number 3: 8,985; copy number 4: 259; copy number 5: 93; copy number 6: 108; copy number 8: 34; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MR-01A-31D-A27J-01): tumor purity 0.32, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 237 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:133,117,004–133,119,052, 1 gene, copy number 6: AC011755.1.
- chr7:84,847,877–99,735,102, 236 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,448. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
